Somatic mutation profile of tumor specimen ALCH-B1T6-TTP1-A (aliquot ALCH-B1T6-TTP1-A-10-0-D-A76I-36) from ALCHEMIST case ALCH-B1T6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.8 years (25,118 days).
Specimen ALCH-B1T6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2272570c-0061-41b0-81bf-e9cd9f48c72d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1T6-NB1-A (Blood Derived Normal), aliquot ALCH-B1T6-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37f56f87-4874-42a7-9715-f366a50eb510

The open-access MAF lists 211 somatic variants for this specimen: 148 protein-altering or splice-affecting, 40 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 40, Intron 9, Nonsense Mutation 9, 3'UTR 5, RNA 4, Splice Region 4, 5'Flank 3, Splice Site 3, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA3 | c.3184T>C p.F1062L | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV57051463; called by muse, mutect2, varscan2
- ADCY2 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100604179, COSV57862658; called by muse, mutect2
- ADGRG4 | c.5581G>T p.V1861F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs757043659; called by muse, mutect2
- ADGRL4 | c.1981T>G p.F661V | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1364531787; called by muse, mutect2
- AFF2 | c.2406G>T p.W802C | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104377229; called by muse, mutect2
- APBA1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs776047651; called by muse, mutect2
- ARHGAP4 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs781890346; called by muse, mutect2
- ARL10 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.168); catalogued as rs200436684; called by muse, mutect2, varscan2
- ATP11B | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | catalogued as COSV60030525; called by muse, mutect2
- C4orf19 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52649193; called by muse, mutect2
- CPS1 | c.2792T>G p.L931R | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV51802695; called by muse, mutect2
- CRHBP | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.119); catalogued as COSV57187422; called by muse, mutect2
- CSMD3 | c.10965G>A p.R3655= (on ENST00000297405 / NM_001363185.1; = p.R3486= on NM_052900.3) | Splice Region (SNP) | VAF 16/274 reads (6%) | catalogued as rs1187505973; called by muse, mutect2
- CSRP1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 29/490 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1419789850; called by muse, mutect2
- DAP3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs1224997587; called by muse, mutect2, varscan2
- DGKA | c.2064-4A>G | Splice Region (SNP) | VAF 17/209 reads (8%) | catalogued as rs761869075; called by muse, mutect2
- ESRRG | c.167A>C p.H56P | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV100752202, COSV63156032; called by muse, mutect2, varscan2
- F8 | c.5107G>A p.E1703K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs781901822; called by muse, mutect2
- F9 | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as CM940554; called by muse, mutect2
- FPGS | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1406338103; called by muse, mutect2
- GALNT7 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53928491; called by muse, mutect2
- GPC3 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV63673637; called by muse, mutect2
- HTR1B | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100885401; called by muse, mutect2
- LMNB2 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as rs200356238; called by muse, mutect2
- MED13L | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 19/299 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV99929759; called by muse, mutect2
- MED14 | c.4337T>G p.L1446R | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59948058; called by muse, mutect2
- MYH8 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67967321; called by muse, mutect2, varscan2
- NDN | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1454287617, COSV59359037; called by muse, mutect2
- NEUROD1 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54550557; called by muse, mutect2
- NF1 | c.7063-2A>G p.X2355_splice (on ENST00000358273 / NM_001042492.3; = p.X2334_splice on NM_000267.3) | Splice Site (SNP) | VAF 21/341 reads (6%) | catalogued as CS076640, COSV62198535, COSV62204118; called by muse, mutect2
- NLGN4X | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 40/515 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV52018138, COSV99320844; called by muse, mutect2
- NOTCH4 | c.5419G>A p.A1807T | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs751250725; called by muse, mutect2
- OR4M1 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV60059297; called by muse, mutect2, varscan2
- OR5M1 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1342285331; called by muse, mutect2
- PARP1 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.209); catalogued as rs1558233876; called by muse, mutect2
- PCDHA8 | c.1925C>G p.S642C | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1554139882, COSV65324074, COSV65326711; called by muse, mutect2
- PDZD2 | c.7450G>A p.E2484K | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1448791109, COSV56867707; called by muse, mutect2
- PGLYRP2 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV52996591; called by muse, mutect2
- PNLIPRP2 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV53945998; called by muse, mutect2
- POTEC | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV100743936, COSV100744047; called by muse, mutect2
- PPP1R16B | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs745855682, COSV55384115; called by muse, mutect2
- PRG4 | c.2362del p.E788Nfs*124 | Frame Shift Del (DEL) | VAF 33/298 reads (11%) | catalogued as COSV63356541; called by mutect2, pindel, varscan2
- SCN4B | c.324G>C p.K108N | Missense Mutation (SNP) | VAF 19/457 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as COSV61252506; called by muse, mutect2
- SCP2 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 31/493 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101026805; called by muse, mutect2
- TAB3 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1446975453; called by muse, mutect2
- TTC12 | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs781888970; called by muse, mutect2
- VSIG8 | c.729C>A p.N243K | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773471965; called by muse, mutect2, varscan2
- WDR46 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1244270891, COSV65841861; called by muse, mutect2, varscan2
- ZBBX | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.089); catalogued as COSV56799495; called by muse, mutect2
- ZNF579 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs975556209, COSV57638206; called by muse, mutect2, varscan2
- ACACB | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2
- ADAM19 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 16/370 reads (4%) | called by muse, mutect2
- AKR1D1 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- ARFGEF2 | c.1326A>C p.K442N | Missense Mutation (SNP) | VAF 53/710 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.344); called by muse, mutect2
- ATP9A | c.770C>G p.T257R | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BMP15 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- BMP15 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- BVES | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); called by muse, mutect2
- C7orf25 | c.-22+6G>A | Splice Region (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- CCDC63 | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDK20 | c.621G>C p.K207N (on ENST00000325303 / NM_001039803.3; = p.K186N on NM_012119.4) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- CFAP52 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- COL1A2 | c.1864-6C>A | Splice Region (SNP) | VAF 27/397 reads (7%) | called by muse, mutect2
- COL24A1 | c.3263T>A p.I1088K | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.065); called by muse, mutect2
- CPT1A | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRB1 | c.1802G>A p.S601N | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CSMD2 | c.2975A>T p.Q992L | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.388); called by muse, mutect2
- DHX35 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2
- DLG2 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2
- DSCAM | c.4656C>A p.N1552K | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DST | c.19681G>T p.D6561Y (on ENST00000361203 / NM_001374722.1; = p.D4258Y on NM_015548.5) | Missense Mutation (SNP) | VAF 39/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EDNRB | c.648C>G p.I216M (on ENST00000377211 / NM_001201397.1; = p.I126M on NM_000115.5) | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2
- EIF3D | c.1005C>A p.Y335* | Nonsense Mutation (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- ERCC6L2 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ERVW-1 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- EVA1B | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); called by muse, mutect2
- FAM135B | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM161A | c.1764G>C p.K588N | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2
- FAM83G | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT2 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, varscan2
- GYS2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); called by muse, mutect2
- HUWE1 | c.12979C>G p.R4327G | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IDS | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 38/447 reads (9%) | called by muse, mutect2
- IGHG1 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- IGKV6D-21 | c.236C>G p.S79W | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- IGSF9 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL4R | c.1548C>A p.D516E | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.039); called by muse, mutect2
- IMMT | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ITIH6 | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.303); called by muse, mutect2
- KIAA1210 | c.1880G>C p.G627A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2
- KLHL12 | c.733A>G p.S245G | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); called by muse, mutect2
- KMT2C | c.10840G>A p.D3614N | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- LPCAT1 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- LRRC52 | c.468C>A p.D156E | Missense Mutation (SNP) | VAF 35/536 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- LRRC52 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 35/541 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); called by muse, mutect2
- LRRTM1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); called by muse, mutect2
- LZTFL1 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.296); called by muse, mutect2
- MBD1 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2
- MBTPS2 | c.1205A>T p.H402L | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- MED1 | c.2558C>G p.S853C | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MED1 | c.1973C>G p.S658* | Nonsense Mutation (SNP) | VAF 29/374 reads (8%) | called by muse, mutect2
- MUC16 | c.4399G>C p.E1467Q | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- MUC17 | c.12622T>C p.S4208P | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MUC6 | c.767C>A p.A256E | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2
- NACC2 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NID2 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- NLGN1 | c.2376G>T p.Q792H | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NPAS1 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2
- NUDCD1 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PBXIP1 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCLO | c.3336G>C p.Q1112H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- PHF3 | c.4963G>C p.A1655P | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PIGS | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- PKHD1L1 | c.11650C>A p.Q3884K | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.17); called by muse, mutect2
- POP1 | c.2219G>A p.R740K | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.025); called by muse, mutect2
- POU3F3 | c.1323C>A p.D441E | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- PRKCB | c.1505G>T p.C502F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTK2 | c.3088G>C p.D1030H | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTK2B | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- RAB3GAP2 | c.1046G>T p.W349L | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RB1CC1 | c.4338-2A>G p.X1446_splice | Splice Site (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RPE65 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2
- RTP5 | c.189G>C p.W63C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SDK2 | c.5937G>C p.E1979D | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- SGK2 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.06); called by muse, mutect2
- SHANK2 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIGLEC8 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC41A2 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMARCAD1 | c.1234G>C p.A412P | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- SMC1A | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- SPATA31E1 | c.2629C>G p.P877A | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2
- SRPK3 | c.520T>A p.W174R | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYNCRIP | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAAR5 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- TCHH | c.4192C>A p.Q1398K | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TLR7 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TM4SF19 | c.32C>G p.S11* | Nonsense Mutation (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- TRIM32 | c.1920C>G p.I640M | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2
- UBR1 | c.4836-2A>T p.X1612_splice | Splice Site (SNP) | VAF 27/370 reads (7%) | called by muse, mutect2
- WDR88 | c.1256A>G p.D419G | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- WWC3 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.167); called by muse, mutect2
- XCL2 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); called by muse, mutect2
- XRN1 | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- ZAN | c.7744G>C p.D2582H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2
- ZFHX4 | c.3876C>G p.N1292K | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZGRF1 | c.3718G>C p.E1240Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2
- ACSF2 | c.438G>A p.Q146= | Silent (SNP) | VAF 23/196 reads (12%) | catalogued as rs1035834291; called by muse, mutect2, varscan2
- ADAMTS19 | c.1659G>A p.Q553= | Silent (SNP) | VAF 19/400 reads (5%) | catalogued as COSV50753008; called by muse, mutect2
- ADGRG2 | c.75T>C p.L25= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- AMBN | c.1164C>A p.T388= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- CCDC86 | c.492C>T p.Y164= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- CEMIP | c.1401C>T p.V467= | Silent (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- CPEB4 | c.372G>A p.S124= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as rs920565677, COSV54170095; called by muse, mutect2
- DNAH10 | c.5592C>G p.G1864= (on ENST00000409039; = p.G1803= on NM_207437.3) | Silent (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- DNAJC12 | c.114T>C p.A38= | Silent (SNP) | VAF 14/249 reads (6%) | called by muse, mutect2
- EXOC3L2 | c.1278C>T p.T426= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs763388471; called by muse, mutect2
- F9 | c.597G>T p.V199= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV54379435; called by muse, mutect2
- GDAP1L1 | c.1005G>A p.K335= | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as COSV100697629; called by muse, mutect2
- GDPD2 | c.1491C>A p.T497= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- GPRC6A | c.963C>A p.G321= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- GRIN2C | c.3660C>A p.P1220= | Silent (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- HUWE1 | c.7146G>C p.L2382= | Silent (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2
- KCNQ3 | c.789G>A p.T263= | Silent (SNP) | VAF 38/473 reads (8%) | catalogued as rs762086066; ClinVar: likely benign; called by muse, mutect2
- KDM6A | c.60T>C p.D20= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs1239808864; called by muse, mutect2
- KLHL12 | c.612G>T p.V204= | Silent (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- KMT2C | c.3126G>A p.Q1042= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- LCMT2 | c.432C>T p.P144= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1432520697; called by muse, mutect2, varscan2
- MFSD3 | c.1014C>G p.V338= | Silent (SNP) | VAF 14/293 reads (5%) | catalogued as COSV56740970; called by muse, mutect2
- NEUROG1 | c.393C>T p.I131= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- NKAIN2 | c.270A>G p.S90= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2
- PCDHA5 | c.1410C>G p.G470= | Silent (SNP) | VAF 13/332 reads (4%) | catalogued as COSV65357486; called by muse, mutect2
- PCDHB1 | c.921C>A p.L307= | Silent (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- PHF20L1 | c.2295C>T p.A765= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- PLEKHH3 | c.1818C>T p.R606= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- PROM2 | c.60G>C p.L20= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs201917939, COSV58297599; called by muse, mutect2
- RIC1 | c.2304C>T p.I768= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs993347581; called by muse, mutect2
- RPL36 | c.63G>C p.V21= | Silent (SNP) | VAF 19/237 reads (8%) | called by muse, mutect2
- RSPO3 | c.132C>A p.G44= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.465G>C p.V155= (on ENST00000291707 / NM_053003.4; = p.V37= on NM_033329.2) | Silent (SNP) | VAF 19/438 reads (4%) | catalogued as rs1020763768; called by muse, mutect2
- SLC4A4 | c.2565G>A p.L855= (on ENST00000264485 / NM_001098484.3; = p.L811= on NM_003759.4) | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as COSV52623273; called by muse, mutect2
- STARD9 | c.9366C>T p.D3122= | Silent (SNP) | VAF 16/251 reads (6%) | catalogued as rs1444581146; called by muse, mutect2
- TEX13A | c.804G>T p.R268= | Silent (SNP) | VAF 28/387 reads (7%) | called by muse, mutect2
- TP53I13 | c.213C>A p.P71= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV56196572; called by muse, mutect2, varscan2
- UTP20 | c.7344A>G p.E2448= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as rs1565808773; called by muse, mutect2
- ZDHHC1 | c.1392G>T p.P464= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- ZNF564 | c.63G>A p.L21= | Silent (SNP) | VAF 20/286 reads (7%) | catalogued as rs778253310; called by muse, mutect2
- ARMCX4 | c.1039-4142C>A | Intron (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ASCC1 | c.*174G>C | 3'UTR (SNP) | VAF 28/584 reads (5%) | catalogued as COSV100403920; called by muse, mutect2
- C12orf57 | c.229+24G>C | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- C8orf31 | n.766T>A | RNA (SNP) | VAF 24/277 reads (9%) | called by muse, mutect2
- CLC | c.*47G>C | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- EVX1 | chr7:27239406 G>A | 5'Flank (SNP) | VAF 7/51 reads (14%) | catalogued as rs768638265; called by muse, mutect2, varscan2
- FAM174B | c.*252C>G | 3'UTR (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- FAM177B | c.242-425C>T | Intron (SNP) | VAF 16/189 reads (8%) | called by muse, mutect2
- FST | c.-35G>T | 5'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- GP6 | c.*217A>T | 3'UTR (SNP) | VAF 34/518 reads (7%) | called by muse, mutect2
- HOXB4 | chr17:48579933 G>A | 5'Flank (SNP) | VAF 14/436 reads (3%) | called by muse, mutect2
- HOXB6 | c.-79+2255G>T | Intron (SNP) | VAF 29/161 reads (18%) | catalogued as rs1301761250; called by muse, mutect2, varscan2
- MAP7D2 | c.595+1992C>A | Intron (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- NGRN | c.-31A>G | 5'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- NOC2LP2 | n.1545C>A | RNA (SNP) | VAF 19/316 reads (6%) | called by muse, mutect2
- PIPSL | n.1645A>G | RNA (SNP) | VAF 31/283 reads (11%) | catalogued as rs201505257; called by muse, mutect2, varscan2
- PLG | c.50-34G>C | Intron (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- RAB17 | c.435+654C>T | Intron (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- RPSAP52 | n.1002G>T | RNA (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- SCOC | c.*28A>G | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- TTN | c.10360+5039A>G | Intron (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- UBQLN1 | chr9:83712678 G>C | 5'Flank (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- WDR45 | c.235+143C>G | Intron (SNP) | VAF 3/29 reads (10%) | catalogued as COSV59875458; called by muse, mutect2
